Gene-level copy-number profile of tumor specimen C3L-09616-02 from CPTAC case C3L-09616, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.1 years (19,764 days).
Specimen C3L-09616-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2160bdde-59d6-4b30-81b9-54e0e815e879.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09616-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/d10ccada-1836-4e03-b7ba-6a937c109cff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 79; copy number 2: 10,865; copy number 3: 667; copy number 4: 43,978; copy number 5: 316; copy number 6: 2,844; copy number 8: 151.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:128,809,700–128,875,224, 1 gene (within-gene range 0–4): JADE1.
- chr4:181,522,666–181,523,001, 1 gene: AC093840.1.
- chr8:7,926,337–7,952,413, 2 genes: ZNF705B, DEFB108A.
- chr9:9,090,898–9,442,380, 2 genes (within-gene range 0–2): RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
